MMRF case MMRF_2213 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0e41ffbc-d45a-4327-91bd-cdf42bdc405d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.3 years (23,124 days); ISS stage: III; Days to last known disease status: 888 days (2.4 years); Days to last follow up: 888 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 153 days; Days to treatment end: 153 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 312 days; Days to treatment end: 356 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 356 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 0): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 747 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 7.48 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 5.7 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 180 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 3.13 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 6.16 mmol/L.
- Day 85 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Hemoglobin 6.94 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 5.83 mmol/L.
- Day 181 (ECOG 1): Hemoglobin 5.39 mmol/L; Leukocytes 14.2 ×10⁹/L; Absolute Neutrophil 9.8 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.03 mmol/L; Albumin 20 g/L; Total Protein 6.1 g/dL; Glucose 5.89 mmol/L.
- Day 265 (ECOG 2): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.38 mg/dL; Immunoglobulin G 8.77 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 10.6 ×10⁹/L; Absolute Neutrophil 9.7 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.2 mmol/L; Albumin 32 g/L; Total Protein 6 g/dL; Glucose 5.23 mmol/L.
- Day 356 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.64 mg/dL; Hemoglobin 6.7 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 142 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.45 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 4.07 mmol/L.
- Day 459 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Hemoglobin 6.82 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.01 mmol/L.
- Day 522 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 8.25 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 5.06 mmol/L.
- Day 888 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 7.18 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 164 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 3.58 mmol/L.

Other clinical attributes
- Day -1: Weight: 44 kg; Height: 155 cm.

Biospecimens (2 samples)
- Sample MMRF_2213_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_2213_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
